Surgical pathology report (de-identified scan), TCGA case TCGA-21-1081, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Fox Chase Cancer Center, specimen TCGA-21-1081-01A (Primary Tumor).

[page 1 of 2]
Clinical History/Diagnosis: Not entered.

Source of Specimen(s):

A: R2 LYMPH NODE
B: R4 LYMPH NODE
C: R4 LYMPH NODE
D: LEVEL 7 LYMPH NODE
E: CYTOLOGY
F: PORTION OF 6TH RIB
G: LLL LUNG
H: LEVEL 5 LN

Gross Description:

GROSS DESCRIPTION: Received fresh is a 1.0cm in greatest dimension gray- black anthracotic stained lymph node. It is submitted in toto in one block.

DESIGNATION OF SECTIONS: 8

SUMMARY OF SECTIONS: Undesignated - 1.

SOURCE OF TISSUE: 9 - SENT TO CYTOLOGY.

Final Diagnosis:

DIAGNOSIS:

1. LYMPH NODES, R2, BIOPSY:
- TWO LYMPH NODES NEGATIVE FOR TUMOR (0/2).
2. LYMPH NODE, R4, BIOPSY:
- ONE LYMPH NODE NEGATIVE FOR TUMOR (0/1).
3. LYMPH NODES, R4, BIOPSY:
- TWO LYMPH NODES BOTH NEGATIVE FOR TUMOR (0/1).
4. LYMPH NODES, LEVEL 7, BIOPSY:
- TWO LYMPH NODES BOTH NEGATIVE FOR TUMOR (0/2).
5. CYTOLOGY
6. PORTION OF 6TH RIB, EXCISION:
- NO TUMOR SEEN.
7. LUNG, LEFT LOWER LOBE, LOBECTOMY:

[page 2 of 2]
- POORLY DIFFERENTIATED SQUAMOUS CELL CARCINOMA (8.5 CM.) WITH
INVASION OF

PLEURA.

- LYMPHATIC INVASION PRESENT.
- METASTATIC CARCINOMA IN ONE OF TWO HILAR LYMPH NODES (1/2).
- NEGATIVE BRONCHIAL AND VASCULAR MARGINS.
- NON-NEOPLASTIC LUNG SHOWS ACUTE BRONCHOPNEUMONIA.

8. LYMPH NODE, LEVEL 5, BIOPSY:

- CALCIFIED GRANULOMA, NO TUMOR SEEN IN ONE LYMPH NODE (0/1).

SYNOPTIC REPORT FOR LUNG CANCER

A NEOPLASM IS PRESENT

LOCATION OF THE TUMOR IS LEFT LOWER LOBE

THE HISTOLOGIC CLASSIFICATION OF THE TUMOR IS SQUAMOUS CELL
(EPIDERMOID)

CARCINOMA, NON-KERATINIZING TYPE

THE GRADE OF THE TUMOR IS POORLY DIFFERENTIATED (GRADE III)

THE MAXIMUM DIMENSION OF THE TUMOR IS 8.5 CM.

LYMPHATIC INVASION BY TUMOR IS PRESENT

VENOUS INVASION BY TUMOR IS ABSENT

ARTERIAL INVASION BY TUMOR IS ABSENT

INVASION THROUGH THE PLEURA BY TUMOR IS PRESENT

TUMOR NECROSIS IS MODERATE

THE NON-NEOPLASTIC LUNG TISSUE SHOWS ACUTE BRONCHOPNEUMONIA.

LYMPH NODES DEMONSTRATE NO EXTRACAPSULAR EXTENSION OF TUMOR

THE TOTAL NUMBER OF NODES EXAMINED IS: 9

THE TOTAL NUMBER OF POSITIVE NODES IS: 1 (HILAR LYMPH NODES)

STAGING DATA

T2

N-1

Source: NCI Genomic Data Commons file 5b55bb68-a083-46ac-a024-33d7a70f90fb (TCGA-21-1081.B7EB9E52-9C41-4398-9CFB-7832A6183258.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).